TARGET case TARGET-30-PALVXL — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/31a73262-fd38-572b-9d39-d970492c6394

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.6 years (1,298 days); Year of diagnosis: 2002; Days to last follow up: 190 days; INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PALVXL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
